Gene-level copy-number profile of tumor specimen TCGA-NP-A5H1-01A from TCGA case TCGA-NP-A5H1, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.5 years (24,299 days).
Specimen TCGA-NP-A5H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b57477f-dee7-4d8e-97fd-f6e4d30c5ebc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-NP-A5H1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/2f7cbb0c-dd67-48bb-a245-ad725d3c5394

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 27,320; copy number 2: 31,014; copy number 3: 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:143,846,097–143,934,776, 6 genes: AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5.
- chr1:248,573,801–248,655,528, 6 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T27.
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–1): AL672310.1.
- chr6:170,695,313–170,737,777, 2 genes: AL731661.1, AL731684.1.
- chr9:22,747,700–22,768,316, 2 genes (within-gene range 0–1): CLIC4P1, AC017067.1.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 24,976. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
